CPTAC case C3L-02741 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/717c0912-b1bf-40f4-abbf-bcb2ec4f9d2a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1958; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 59.6 years (21,785 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Tumor grade: G1; Residual disease: RX; Days to last known disease status: 1,869 days (5.1 years); Days to last follow up: 1,869 days (5.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.2 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 3; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 414 days (1.1 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 750 days (2.1 years); Disease response: Complete Response.
- Days to follow up: 750 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 1,139 days (3.1 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,504 days (4.1 years); Disease response: Tumor Free; ECOG performance status: 0.
- Follow-up contact recording only the day: day 1,869.

Other clinical attributes
- Weight: 108.86 kg; Height: 154.94 cm; BMI: 45.34; Hormonal contraceptive use: Former User.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02741-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 43 days; Initial weight: 362 mg; Time between clamping and freezing: 24 minutes; Time between excision and freezing: 3 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02741-21: Section location: Endometrium; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-02741-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 43 days; Time between clamping and freezing: 24 minutes; Time between excision and freezing: 3 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02741-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 43 days; Method of sample procurement: Blood Draw.
